Somatic mutation profile of tumor specimen TCGA-S9-A6WQ-01A (aliquot TCGA-S9-A6WQ-01A-12D-A34A-08) from TCGA case TCGA-S9-A6WQ, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 57.9 years (21,133 days).
Specimen TCGA-S9-A6WQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe53ffaa-a85d-4e64-86d9-73a7d9bc8ff8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6WQ-10A (Blood Derived Normal), aliquot TCGA-S9-A6WQ-10A-01D-A34A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4b2380c-67d0-41cb-9f39-025892f2ada2

The open-access MAF lists 36 somatic variants for this specimen: 28 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 24, Silent 8, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 28/90 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>G p.H179D | Missense Mutation (SNP) | VAF 29/79 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AKAP8 | c.1332T>G p.I444M | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99512140; called by muse, mutect2, varscan2
- CCBE1 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 60/154 reads (39%) | catalogued as rs765153557, COSV67949464; called by muse, mutect2, varscan2
- CPA2 | c.46A>G p.I16V | Missense Mutation (SNP) | VAF 22/199 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99744226; called by muse, mutect2, varscan2
- CTR9 | c.1147T>G p.S383A | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.53); catalogued as COSV100797473; called by muse, mutect2, varscan2
- EHMT1 | c.3568C>T p.R1190W | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101135080; called by muse, mutect2, varscan2
- ERAS | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54432656; called by muse, mutect2, varscan2
- GAR1 | c.344A>C p.E115A | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99901988; called by muse, mutect2, varscan2
- ITPRIP | c.126G>C p.Q42H | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV99532694; called by muse, mutect2, varscan2
- LMBR1 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100626801; called by muse, mutect2
- MGA | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 5/94 reads (5%) | catalogued as COSV99579480; called by muse, mutect2
- MYOM3 | c.3952G>A p.A1318T | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); catalogued as COSV100141929; called by muse, mutect2
- NEO1 | c.1541T>C p.M514T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99982638; called by muse, mutect2, varscan2
- NONO | c.562T>C p.S188P | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52136417; called by muse, mutect2, varscan2
- NSL1 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as rs776038764, COSV100875626; called by muse, mutect2, varscan2
- OR51F2 | c.375T>G p.F125L | Missense Mutation (SNP) | VAF 68/203 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.387); catalogued as COSV100438122; called by muse, mutect2, varscan2
- PASD1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV64855120; called by muse, mutect2, varscan2
- PIM2 | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55944051, COSV99900476; called by muse, varscan2
- RHAG | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100006810; called by muse, mutect2
- SNX20 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs751339391, COSV56058051; called by muse, mutect2, varscan2
- SYNE1 | c.8570A>G p.H2857R (on ENST00000367255 / NM_182961.4; = p.H2864R on NM_033071.3) | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.532); catalogued as COSV99575524; called by muse, mutect2, varscan2
- TMEM214 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1418477834, COSV99476497; called by muse, mutect2
- UNC45B | c.1774A>G p.I592V | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99269125; called by muse, mutect2, varscan2
- ZNF624 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100257103, COSV100257404; called by muse, mutect2, varscan2
- ATRX | c.4246_4255del p.Q1416Ifs*71 | Frame Shift Del (DEL) | VAF 27/137 reads (20%) | called by mutect2, pindel, varscan2
- NKX2-2 | c.624_625del p.L208Ffs*101 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- CDX4 | c.435G>A p.K145= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100999150; called by muse, mutect2, varscan2
- NLRP6 | c.2439C>T p.A813= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV100381134; called by muse, mutect2, varscan2
- PELI3 | c.1216C>T p.L406= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs1244348214, COSV100291884; called by muse, mutect2, varscan2
- PIM2 | c.357T>A p.P119= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99900477; called by muse, varscan2
- POLD1 | c.1653G>A p.Q551= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs919580802, COSV101486915; ClinVar: likely benign; called by muse, mutect2, varscan2
- PSMB10 | c.99T>A p.P33= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV99863235; called by muse, mutect2, varscan2
- RPS2 | c.531C>T p.P177= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs200947241, COSV99238911; called by muse, mutect2, varscan2
- TPTE | c.1038A>G p.G346= (on ENST00000618007 / NM_199261.4; = p.G328= on NM_199259.4) | Silent (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
